TCGA case TCGA-19-1388 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Case Western. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/166e76db-ccd8-4760-a517-d2bc8937ea29

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Dead; Days to death: 394 days (1.1 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 58.5 years (21,368 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 21 days; Days to treatment end: 63 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 21 days; Days to treatment end: 63 days; Number of cycles: 1; Treatment dose: 6,020 mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Maintenance Therapy; Days to treatment start: 97 days; Days to treatment end: 250 days; Number of cycles: 6; Treatment dose: 9,000 mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 269 days; Days to treatment end: 328 days; Number of cycles: 1; Treatment dose: 6,000 mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 363 days; Days to treatment end: 377 days (1.0 years); Number of cycles: 2; Treatment dose: 1,750 mg; Route of administration: Intravenous.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 58.9 years (21,516 days); Days to diagnosis: 148 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 148 (post initial treatment): Progression or recurrence: Yes; Days to progression: 148 days.
- Days to follow up: 394 days (1.1 years); Disease response: With Tumor.
- ECOG performance status: 3; Timepoint: Post Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-19-1388-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.8; Intermediate dimension: 0.6; Shortest dimension: 0.4.
  Slide TCGA-19-1388-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-19-1388-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-19-1388-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-19-1388-10C: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 1: Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Concurrent.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Maintenance.
- Drug treatment 3: Pharmaceutical therapy drug name: Avastin.
- Drug treatment 3, Route of administrations: Route of administration: IV.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 394 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 394 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 148 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-19-1388-01A-01D-0591-01): tumor purity 0.65, ploidy 3.49, whole-genome doublings 1.
